Somatic mutation profile of cancer-model specimen HCM-SANG-0294-C15-85A (3D Organoid; aliquot HCM-SANG-0294-C15-85A-01D-A78U-36), derived from the primary tumor of HCMI case HCM-SANG-0294-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G3.
Specimen HCM-SANG-0294-C15-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 68162c36-d9d5-4c44-afd5-5b77b1716330.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-SANG-0294-C15-10A (Blood Derived Normal), aliquot HCM-SANG-0294-C15-10A-01D-A78U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c14396b0-a755-455c-92cc-877415cbe700

The open-access MAF lists 242 somatic variants for this specimen: 141 protein-altering or splice-affecting, 68 silent, 33 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 119, Silent 68, Intron 14, Frame Shift Ins 7, 5'UTR 7, Nonsense Mutation 6, Frame Shift Del 5, RNA 5, 5'Flank 3, 3'Flank 2, Splice Region 2, 3'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNQ2 | c.1229del p.P410Rfs*30 (on ENST00000359125 / NM_172107.4; = p.P400Rfs*12 on NM_004518.6) | Frame Shift Del (DEL) | VAF 112/500 reads (22%) | catalogued as rs886041339, CD094786; ClinVar: pathogenic; called by pindel, varscan2
- TP53 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 592/592 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs786201059, CM076567, CM1212545, COSV52664318, COSV52687201, COSV52688214; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ANKRD30A | c.3192A>C p.E1064D (on ENST00000611781; = p.E1008D on NM_052997.2) | Missense Mutation (SNP) | VAF 44/84 reads (52%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.806); catalogued as rs1295440874; called by muse, mutect2, varscan2
- AOPEP | c.1849C>T p.H617Y (on ENST00000375315 / NM_001193329.1; = p.H518Y on NM_032823.5) | Missense Mutation (SNP) | VAF 43/64 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52994789; called by muse, mutect2, varscan2
- APOA4 | c.454C>A p.Q152K | Missense Mutation (SNP) | VAF 78/264 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.03); catalogued as COSV100759400, COSV63360889; called by muse, mutect2, varscan2
- BIN1 | c.1334C>T p.S445F | Missense Mutation (SNP) | VAF 101/303 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as rs1158338100; called by muse, mutect2, varscan2
- BTNL2 | c.860G>A p.R287H | Missense Mutation (SNP) | VAF 67/350 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0.425); catalogued as rs778673342; called by muse, mutect2, varscan2
- CACNA1H | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 192/192 reads (100%) | SIFT tolerated (0.24); PolyPhen benign (0.019); catalogued as rs761025927; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CARNS1 | c.1198G>C p.G400R | Missense Mutation (SNP) | VAF 98/450 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs900666958; called by muse, mutect2, varscan2
- CDK12 | c.3022C>T p.R1008W | Missense Mutation (SNP) | VAF 79/283 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71000145; called by muse, mutect2, varscan2
- CEP250 | c.1556G>A p.R519Q | Missense Mutation (SNP) | VAF 54/194 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.789); catalogued as rs115893489; called by muse, mutect2, varscan2
- CLCA1 | c.1232C>T p.T411M | Missense Mutation (SNP) | VAF 61/190 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs375829347, COSV52324954; called by muse, mutect2, varscan2
- CSPG4 | c.4354G>A p.E1452K | Missense Mutation (SNP) | VAF 70/264 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as rs774329143; called by muse, mutect2, varscan2
- DMP1 | c.871G>A p.V291I | Missense Mutation (SNP) | VAF 228/764 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.348); catalogued as rs780697576, COSV99219003; called by muse, mutect2, varscan2
- DNAJC30 | c.95G>A p.G32D | Missense Mutation (SNP) | VAF 162/488 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.029); catalogued as rs1554611823, COSV104379773; called by muse, mutect2, varscan2
- ELMO1 | c.2125G>A p.A709T | Missense Mutation (SNP) | VAF 485/847 reads (57%) | SIFT tolerated (0.59); PolyPhen benign (0.015); catalogued as rs918674508, COSV60329852; called by muse, mutect2, varscan2
- EPHA5 | c.1258G>A p.G420S | Missense Mutation (SNP) | VAF 150/526 reads (29%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as rs370503988; called by muse, mutect2, varscan2
- ERVH48-1 | c.451C>T p.R151W | Missense Mutation (SNP) | VAF 9/194 reads (5%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs958234033; called by muse, mutect2
- FZR1 | c.195C>T p.N65= | Splice Region (SNP) | VAF 97/281 reads (35%) | catalogued as rs768223395; called by muse, mutect2, varscan2
- GALNT17 | c.157G>A p.A53T | Missense Mutation (SNP) | VAF 210/320 reads (66%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.017); catalogued as COSV61166417; called by muse, mutect2, varscan2
- GLI3 | c.3040G>A p.E1014K | Missense Mutation (SNP) | VAF 322/727 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.047); catalogued as rs373643864, CM107030; called by muse, mutect2, varscan2
- GOLGA8S | c.1715T>C p.V572A | Missense Mutation (SNP) | VAF 254/402 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as COSV71846641; called by mutect2, varscan2
- H2AC8 | c.265C>A p.R89S | Missense Mutation (SNP) | VAF 73/540 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV99773431; called by muse, mutect2, varscan2
- HUNK | c.1337G>A p.G446E | Missense Mutation (SNP) | VAF 10/119 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as COSV99528609; called by muse, mutect2
- IGHV3-30 | c.150C>G p.S50R | Missense Mutation (SNP) | VAF 446/1326 reads (34%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); catalogued as rs375279439; called by muse, mutect2, varscan2
- IL31 | c.163G>T p.D55Y | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.865); catalogued as COSV100986572; called by muse, varscan2
- IL3RA | c.553C>T p.R185W | Missense Mutation (SNP) | VAF 211/212 reads (100%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.934); catalogued as rs773005678, COSV58429897; called by muse, mutect2, varscan2
- KCTD19 | c.916C>T p.R306C | Missense Mutation (SNP) | VAF 203/681 reads (30%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.446); catalogued as rs749796211, COSV58570995; called by muse, mutect2, varscan2
- KIAA1109 | c.13213G>C p.V4405L | Missense Mutation (SNP) | VAF 69/225 reads (31%) | SIFT tolerated (1); PolyPhen possibly damaging (0.451); catalogued as COSV52667595; called by muse, mutect2, varscan2
- KLF8 | c.407C>A p.P136H | Missense Mutation (SNP) | VAF 231/231 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV63847479; called by muse, mutect2, varscan2
- KRT8 | c.1366A>G p.S456G | Missense Mutation (SNP) | VAF 93/369 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as rs775155645; called by muse, mutect2, varscan2
- LRP1B | c.13304A>G p.K4435R | Missense Mutation (SNP) | VAF 234/349 reads (67%) | SIFT tolerated (0.59); PolyPhen benign (0.006); catalogued as COSV101254879, COSV67186665, COSV67220594; called by muse, mutect2, varscan2
- MAP3K7 | c.1201G>A p.A401T | Missense Mutation (SNP) | VAF 48/119 reads (40%) | SIFT tolerated (0.47); PolyPhen benign (0.017); catalogued as rs751058214, COSV65226275; called by muse, mutect2, varscan2
- MMP11 | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 294/463 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200864019; called by muse, mutect2, varscan2
- MS4A4E | c.238G>T p.V80L | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.622); catalogued as rs199719139; called by muse, mutect2, varscan2
- MYLK2 | c.1564G>A p.V522I | Missense Mutation (SNP) | VAF 137/883 reads (16%) | SIFT tolerated (0.68); PolyPhen benign (0.037); catalogued as rs747657397, COSV65659694; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NKPD1 | c.1949C>T p.P650L | Missense Mutation (SNP) | VAF 80/263 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs765787555; called by muse, varscan2
- NPAP1 | c.3213A>T p.Q1071H | Missense Mutation (SNP) | VAF 142/437 reads (32%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.33); catalogued as rs766197616; called by muse, mutect2, varscan2
- NTRK2 | c.1946C>A p.T649K (on ENST00000323115 / NM_001369534.1; = p.T665K on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 116/445 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV52872959; called by muse, mutect2, varscan2
- OPRK1 | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 61/196 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749949592, COSV55570116; called by muse, mutect2, varscan2
- OR4C6 | c.190T>G p.L64V | Missense Mutation (SNP) | VAF 175/330 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.216); catalogued as COSV58605224, COSV58606549; called by muse, mutect2, varscan2
- PCDH15 | c.1040T>G p.L347R | Missense Mutation (SNP) | VAF 87/194 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV57299220, COSV57350026; called by muse, mutect2, varscan2
- PCDHA1 | c.394G>A p.V132I | Missense Mutation (SNP) | VAF 177/177 reads (100%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.014); catalogued as COSV65373779; called by muse, mutect2, varscan2
- PGBD2 | c.814_815del p.M272Vfs*2 | Frame Shift Del (DEL) | VAF 116/155 reads (75%) | catalogued as rs1558289570; called by mutect2, pindel, varscan2
- PITX1 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 78/78 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54762031, COSV54763201; called by muse, mutect2, varscan2
- PKD2 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 53/167 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); catalogued as rs1392093609; called by muse, mutect2, varscan2
- PLVAP | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 98/316 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.594); catalogued as rs759585750; called by muse, mutect2, varscan2
- POLQ | c.4289dup p.L1430Ffs*5 | Frame Shift Ins (INS) | VAF 34/86 reads (40%) | catalogued as rs755281591, COSV99951761; called by mutect2, varscan2
- RGL2 | c.625C>T p.R209C | Missense Mutation (SNP) | VAF 72/310 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs151195371; called by muse, mutect2, varscan2
- RYR1 | c.10901C>T p.A3634V | Missense Mutation (SNP) | VAF 267/816 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV62089069; called by muse, mutect2, varscan2
- SGCD | c.28C>T p.R10W (on ENST00000435422 / NM_001128209.2; = p.R11W on NM_000337.5) | Missense Mutation (SNP) | VAF 177/177 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs566181541, COSV61911651; called by muse, mutect2, varscan2
- SHISAL1 | c.481C>T p.R161W | Missense Mutation (SNP) | VAF 196/301 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as rs376878869; called by muse, mutect2, varscan2
- SLC6A2 | c.1393G>A p.G465R | Missense Mutation (SNP) | VAF 641/641 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1297555256; called by muse, mutect2, varscan2
- SORCS1 | c.271C>T p.R91W | Missense Mutation (SNP) | VAF 85/264 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV53908958; called by muse, mutect2, varscan2
- SPATA5 | c.334G>A p.G112S | Missense Mutation (SNP) | VAF 185/299 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs773376572; called by muse, mutect2, varscan2
- SPTA1 | c.2876G>A p.R959Q | Missense Mutation (SNP) | VAF 157/415 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.037); catalogued as rs754523316, COSV63750087, COSV63753218; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TNFSF14 | c.77G>A p.R26Q | Missense Mutation (SNP) | VAF 219/376 reads (58%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs150431195; called by muse, mutect2, varscan2
- TREM2 | c.292C>T p.R98W | Missense Mutation (SNP) | VAF 412/810 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as rs147564421, CM132590; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRHDE | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 100/100 reads (100%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as rs1278896797; called by muse, mutect2, varscan2
- TRIM6 | c.998C>T p.P333L | Missense Mutation (SNP) | VAF 248/564 reads (44%) | SIFT tolerated (0.78); PolyPhen probably damaging (0.96); catalogued as rs1214852302, COSV104376274, COSV53478516; called by muse, mutect2, varscan2
- TTC21B | c.1426C>T p.R476C | Missense Mutation (SNP) | VAF 109/346 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as rs756531554; called by muse, mutect2, varscan2
- VPS51 | c.1085G>T p.G362V | Missense Mutation (SNP) | VAF 77/1111 reads (7%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV54206040; called by muse, mutect2
- ZFC3H1 | c.5966A>T p.H1989L | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV66430086; called by muse, mutect2
- ZNF511 | c.470C>T p.T157I | Missense Mutation (SNP) | VAF 92/461 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1259773746; called by muse, mutect2, varscan2
- ZNF843 | c.650G>T p.R217L | Missense Mutation (SNP) | VAF 78/79 reads (99%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.324); catalogued as COSV59847690; called by muse, mutect2, varscan2
- ZRANB3 | c.1835A>C p.K612T | Missense Mutation (SNP) | VAF 53/198 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.036); catalogued as rs773360393; called by muse, mutect2, varscan2
- AASDHPPT | c.308C>G p.P103R | Missense Mutation (SNP) | VAF 70/454 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- AC011455.2 | c.1087G>T p.D363Y | Missense Mutation (SNP) | VAF 138/479 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANKRD20A1 | c.1574G>C p.R525T | Missense Mutation (SNP) | VAF 6/291 reads (2%) | SIFT tolerated (0.05); PolyPhen benign (0.001); called by muse, mutect2
- ANKRD30A | c.4189T>C p.S1397P (on ENST00000611781; = p.S1341P on NM_052997.2) | Missense Mutation (SNP) | VAF 40/73 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- AQR | c.621G>A p.M207I | Missense Mutation (SNP) | VAF 16/263 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2
- ARID1A | c.6494_6495insCATG p.E2165Dfs*61 | Frame Shift Ins (INS) | VAF 256/288 reads (89%) | called by mutect2, varscan2
- ARID1A | c.6499_6502dup p.V2168Gfs*58 | Frame Shift Ins (INS) | VAF 251/278 reads (90%) | called by mutect2*, pindel, varscan2*
- ASIC1 | c.526G>A p.G176R | Missense Mutation (SNP) | VAF 24/180 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, varscan2
- BCL2L14 | c.491G>A p.W164* | Nonsense Mutation (SNP) | VAF 89/284 reads (31%) | called by muse, mutect2, varscan2
- CACNG6 | c.676G>A p.G226R (on ENST00000252729 / NM_145814.1; = p.G155R on NM_031897.2) | Missense Mutation (SNP) | VAF 13/144 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); called by muse, mutect2
- CCDC82 | c.765_786+15del p.X255_splice | Splice Site (DEL) | VAF 109/226 reads (48%) | called by mutect2, pindel
- CDRT1 | c.1595G>C p.R532T | Missense Mutation (SNP) | VAF 94/181 reads (52%) | SIFT tolerated (0.05); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- CFAP46 | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 104/394 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- CHD9 | c.1744dup p.T582Nfs*6 | Frame Shift Ins (INS) | VAF 35/142 reads (25%) | called by mutect2, varscan2
- CREBBP | c.6101G>T p.G2034V | Missense Mutation (SNP) | VAF 10/290 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.012); called by muse, mutect2
- DCBLD2 | c.1576G>T p.D526Y | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- DNAH11 | c.1458G>C p.K486N | Missense Mutation (SNP) | VAF 8/226 reads (4%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2
- DSCAML1 | c.1690G>T p.G564C (on ENST00000321322; = p.G504C on NM_020693.4) | Missense Mutation (SNP) | VAF 27/587 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- GABRG2 | c.731C>A p.S244Y | Missense Mutation (SNP) | VAF 141/141 reads (100%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GAS2L2 | c.2110A>G p.R704G | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- GLI3 | c.4116C>A p.S1372R | Missense Mutation (SNP) | VAF 317/1528 reads (21%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GON4L | c.4662G>C p.E1554D | Missense Mutation (SNP) | VAF 142/438 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.534); called by muse, mutect2, varscan2
- HORMAD1 | c.185G>T p.C62F | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- HUWE1 | c.4897A>C p.S1633R | Missense Mutation (SNP) | VAF 109/238 reads (46%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- IGFBP1 | c.746C>T p.P249L | Missense Mutation (SNP) | VAF 28/436 reads (6%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.737); called by muse, mutect2
- IGHV1OR15-9 | c.49G>T p.A17S | Missense Mutation (SNP) | VAF 156/464 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- IGKV1-27 | c.208A>C p.I70L | Missense Mutation (SNP) | VAF 222/681 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.108); called by mutect2, varscan2
- IMPG1 | c.1616A>G p.Y539C | Missense Mutation (SNP) | VAF 97/201 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- KRT84 | c.710C>T p.A237V | Missense Mutation (SNP) | VAF 252/416 reads (61%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- KRTAP27-1 | c.109C>T p.P37S | Missense Mutation (SNP) | VAF 186/186 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LCN2 | c.245A>T p.K82M | Missense Mutation (SNP) | VAF 132/494 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- LILRB5 | c.64C>T p.Q22* | Nonsense Mutation (SNP) | VAF 24/414 reads (6%) | called by muse, mutect2
- LRFN5 | c.19dup p.Y7Lfs*26 | Frame Shift Ins (INS) | VAF 20/72 reads (28%) | called by mutect2, pindel, varscan2
- LRP1B | c.1424G>T p.C475F | Missense Mutation (SNP) | VAF 11/211 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- MCHR2 | c.379A>T p.M127L | Missense Mutation (SNP) | VAF 87/161 reads (54%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- MKRN3 | c.339G>T p.E113D | Missense Mutation (SNP) | VAF 118/328 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NELL2 | c.1665_1699del p.D555Efs*5 | Frame Shift Del (DEL) | VAF 92/166 reads (55%) | called by mutect2, pindel
- NLRP10 | c.113C>T p.S38F | Missense Mutation (SNP) | VAF 271/597 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- NPR3 | c.1424C>A p.S475* | Nonsense Mutation (SNP) | VAF 136/270 reads (50%) | called by muse, mutect2, varscan2
- NRG1 | c.986A>C p.E329A (on ENST00000405005 / NM_013964.5; = p.E334A on NM_013956.5) | Missense Mutation (SNP) | VAF 70/143 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- OAS1 | c.336G>C p.E112D | Missense Mutation (SNP) | VAF 62/250 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- OR10A3 | c.508G>A p.G170S | Missense Mutation (SNP) | VAF 98/474 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- PABPC5 | c.775T>A p.L259M | Missense Mutation (SNP) | VAF 241/241 reads (100%) | SIFT tolerated (1); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- PADI6 | c.1916G>A p.G639E | Missense Mutation (SNP) | VAF 22/542 reads (4%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.74); called by muse, mutect2
- PCDH15 | c.4435C>A p.Q1479K | Missense Mutation (SNP) | VAF 111/202 reads (55%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- PCDH15 | c.2881A>G p.S961G | Missense Mutation (SNP) | VAF 71/163 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- PDE1A | c.1122G>C p.W374C | Missense Mutation (SNP) | VAF 66/218 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PES1 | c.94G>T p.A32S | Missense Mutation (SNP) | VAF 22/254 reads (9%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.627); called by muse, mutect2
- PFDN6 | c.170_185del p.F57Wfs*3 | Frame Shift Del (DEL) | VAF 16/60 reads (27%) | called by mutect2, pindel
- PRH2 | c.111C>G p.D37E | Missense Mutation (SNP) | VAF 262/579 reads (45%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- PTN | c.123del p.V42* | Frame Shift Del (DEL) | VAF 20/50 reads (40%) | called by mutect2, varscan2
- PTPRD | c.2155G>C p.E719Q | Missense Mutation (SNP) | VAF 59/118 reads (50%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- QSOX1 | c.625C>T p.Q209* | Nonsense Mutation (SNP) | VAF 79/217 reads (36%) | called by muse, mutect2, varscan2
- RP1L1 | c.1654C>T p.P552S | Missense Mutation (SNP) | VAF 30/518 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0.001); called by muse, mutect2
- SLC43A1 | c.223dup p.M75Nfs*152 | Frame Shift Ins (INS) | VAF 87/507 reads (17%) | called by mutect2, varscan2
- SLC43A1 | c.222delinsTA p.E74Dfs*153 | Frame Shift Ins (INS) | VAF 58/559 reads (10%) | called by mutect2*, pindel, varscan2*
- SNRPC | c.8+8G>A | Splice Region (SNP) | VAF 11/334 reads (3%) | called by muse, mutect2
- SNTG2 | c.259A>G p.S87G | Missense Mutation (SNP) | VAF 220/357 reads (62%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SPATS1 | c.323C>T p.S108L | Missense Mutation (SNP) | VAF 123/270 reads (46%) | SIFT tolerated (0.38); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- STAMBPL1 | c.608C>T p.S203L | Missense Mutation (SNP) | VAF 90/176 reads (51%) | SIFT tolerated (0.67); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- TBC1D19 | c.447C>G p.F149L | Missense Mutation (SNP) | VAF 47/87 reads (54%) | SIFT tolerated (0.12); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- TENT4A | c.1975C>T p.Q659* | Nonsense Mutation (SNP) | VAF 18/551 reads (3%) | called by muse, mutect2
- TIGD4 | c.652G>T p.V218F | Missense Mutation (SNP) | VAF 145/230 reads (63%) | SIFT tolerated (0.08); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- TNN | c.3040G>A p.V1014I | Missense Mutation (SNP) | VAF 158/228 reads (69%) | SIFT tolerated (0.4); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TPO | c.1697T>C p.V566A | Missense Mutation (SNP) | VAF 172/603 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- TRAPPC3L | c.326A>G p.K109R | Missense Mutation (SNP) | VAF 96/182 reads (53%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- TRIL | c.1903C>G p.R635G | Missense Mutation (SNP) | VAF 164/394 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TRIM6-TRIM34 | c.1828A>C p.M610L | Missense Mutation (SNP) | VAF 147/302 reads (49%) | SIFT tolerated (0.71); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TRIM64C | c.216G>T p.K72N | Missense Mutation (SNP) | VAF 529/1182 reads (45%) | SIFT tolerated (0.43); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- TTLL5 | c.2382_2387+10del p.X794_splice | Splice Site (DEL) | VAF 73/89 reads (82%) | called by mutect2, pindel, varscan2
- UNC80 | c.2227G>T p.E743* | Nonsense Mutation (SNP) | VAF 10/218 reads (5%) | called by muse, mutect2
- USP17L1 | c.988T>C p.C330R | Missense Mutation (SNP) | VAF 279/316 reads (88%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- WDR97 | c.4630C>T p.P1544S | Missense Mutation (SNP) | VAF 16/462 reads (3%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); called by muse, mutect2
- XKR5 | c.1174C>A p.Q392K | Missense Mutation (SNP) | VAF 180/375 reads (48%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- ZAN | c.1146C>G p.F382L | Missense Mutation (SNP) | VAF 32/556 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.854); called by muse, mutect2
- ABCA13 | c.13338G>A p.E4446= | Silent (SNP) | VAF 38/634 reads (6%) | catalogued as COSV101291455; called by muse, mutect2
- AMD1 | c.529T>C p.L177= | Silent (SNP) | VAF 22/300 reads (7%) | catalogued as rs1049705, COSV64387301; called by muse, mutect2
- ANAPC1 | c.2469T>C p.I823= | Silent (SNP) | VAF 23/63 reads (37%) | called by muse, mutect2, varscan2
- ATP10A | c.1431G>A p.S477= | Silent (SNP) | VAF 194/560 reads (35%) | catalogued as rs377377929; called by muse, mutect2, varscan2
- BRPF1 | c.3591G>A p.Q1197= | Silent (SNP) | VAF 101/195 reads (52%) | catalogued as COSV57353523; called by muse, mutect2, varscan2
- CARD11 | c.681C>T p.L227= | Silent (SNP) | VAF 18/312 reads (6%) | catalogued as COSV62719489; called by muse, mutect2
- CDC25A | c.1017A>T p.G339= | Silent (SNP) | VAF 8/137 reads (6%) | called by muse, mutect2
- CNOT6L | c.486C>T p.L162= (on ENST00000504123 / NM_001286790.2; = p.L157= on NM_144571.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 65/170 reads (38%) | catalogued as rs753668373, COSV53701780; called by muse, mutect2, varscan2
- CNTN1 | c.2955A>G p.G985= | Silent (SNP) | VAF 134/429 reads (31%) | called by muse, mutect2, varscan2
- COL2A1 | c.3813C>T p.S1271= | Silent (SNP) | VAF 15/482 reads (3%) | called by muse, mutect2
- DZIP3 | c.538T>C p.L180= | Silent (SNP) | VAF 49/99 reads (49%) | called by muse, mutect2, varscan2
- EEF1G | c.117T>C p.H39= | Silent (SNP) | VAF 18/452 reads (4%) | catalogued as COSV57745138; called by muse, mutect2
- EXTL3 | c.2256C>T p.D752= | Silent (SNP) | VAF 182/385 reads (47%) | catalogued as rs781276373, COSV55037022; called by muse, mutect2, varscan2
- FAM102B | c.75T>C p.N25= | Silent (SNP) | VAF 11/348 reads (3%) | catalogued as rs1302554675, COSV64240178; called by muse, mutect2
- FAM217A | c.555T>C p.N185= | Silent (SNP) | VAF 180/318 reads (57%) | catalogued as rs756907917; called by muse, mutect2, varscan2
- FAM83C | c.156C>T p.L52= | Silent (SNP) | VAF 417/853 reads (49%) | called by muse, mutect2, varscan2
- FER1L6 | c.3444C>T p.D1148= | Silent (SNP) | VAF 76/233 reads (33%) | called by muse, mutect2, varscan2
- FIGN | c.2196T>G p.A732= | Silent (SNP) | VAF 76/258 reads (29%) | called by muse, mutect2, varscan2
- FLNC | c.4395C>T p.F1465= | Silent (SNP) | VAF 116/220 reads (53%) | called by muse, mutect2, varscan2
- GALM | c.594G>A p.A198= | Silent (SNP) | VAF 27/215 reads (13%) | catalogued as rs528092061; called by muse, mutect2, varscan2
- GDPGP1 | c.225G>C p.L75= | Silent (SNP) | VAF 157/482 reads (33%) | called by muse, mutect2, varscan2
- GRIN3B | c.1011C>T p.F337= | Silent (SNP) | VAF 12/52 reads (23%) | called by muse, mutect2, varscan2
- H2AW | c.345A>G p.V115= | Silent (SNP) | VAF 66/484 reads (14%) | catalogued as rs761793820, COSV64209514; called by muse, mutect2
- HIC1 | c.492C>T p.G164= (on ENST00000322941 / NM_001098202.1; = p.G145= on NM_006497.4) | Silent (SNP) | VAF 60/121 reads (50%) | called by muse, mutect2, varscan2
- HMCN1 | c.14052A>C p.G4684= | Silent (SNP) | VAF 58/230 reads (25%) | called by muse, mutect2, varscan2
- HYDIN | c.7593G>A p.A2531= | Silent (SNP) | VAF 107/108 reads (99%) | catalogued as rs185945967, COSV59253502; called by muse, mutect2, varscan2
- IL31 | c.78G>A p.T26= | Silent (SNP) | VAF 96/278 reads (35%) | catalogued as rs557327465; called by muse, varscan2
- KATNIP | c.4431T>C p.A1477= | Silent (SNP) | VAF 194/195 reads (99%) | called by muse, mutect2, varscan2
- KIF2B | c.1509C>G p.L503= | Silent (SNP) | VAF 10/224 reads (4%) | called by muse, mutect2
- KMT2D | c.14673G>A p.Q4891= | Silent (SNP) | VAF 10/37 reads (27%) | called by muse, mutect2, varscan2
- KRT83 | c.285C>T p.P95= | Silent (SNP) | VAF 40/1058 reads (4%) | called by muse, mutect2
- MID2 | c.1425G>T p.G475= | Silent (SNP) | VAF 8/121 reads (7%) | called by muse, mutect2
- MRTFA | c.2703C>G p.A901= | Silent (SNP) | VAF 11/25 reads (44%) | called by muse, mutect2, varscan2
- MUC19 | c.1476C>T p.N492= | Silent (SNP) | VAF 35/109 reads (32%) | catalogued as rs1218524420; called by muse, mutect2, varscan2
- MYBPC3 | c.1545C>T p.N515= | Silent (SNP) | VAF 141/281 reads (50%) | catalogued as rs771230605, CD115914, COSV57029249; called by muse, mutect2, varscan2
- MYF6 | c.93T>A p.S31= | Silent (SNP) | VAF 40/351 reads (11%) | called by muse, mutect2, varscan2
- NCOR2 | c.6630G>T p.S2210= | Silent (SNP) | VAF 102/153 reads (67%) | called by muse, mutect2, varscan2
- NEURL1 | c.318C>G p.V106= | Silent (SNP) | VAF 11/158 reads (7%) | called by muse, mutect2
- NFRKB | c.1077G>A p.K359= (on ENST00000446488 / NM_001143835.2; = p.K384= on NM_006165.3) | Silent (SNP) | VAF 74/237 reads (31%) | called by muse, mutect2, varscan2
- NISCH | c.1908C>T p.G636= | Silent (SNP) | VAF 70/149 reads (47%) | catalogued as rs762833811; called by muse, mutect2, varscan2
- NXPE4 | c.309C>T p.T103= | Silent (SNP) | VAF 101/333 reads (30%) | called by muse, mutect2, varscan2
- NXPH1 | c.12G>A p.A4= | Silent (SNP) | VAF 107/733 reads (15%) | catalogued as rs781301643; called by muse, mutect2, varscan2
- OR9I1 | c.204G>T p.L68= | Silent (SNP) | VAF 23/215 reads (11%) | called by muse, mutect2, varscan2
- PRPF8 | c.2100G>A p.G700= | Silent (SNP) | VAF 10/329 reads (3%) | called by muse, mutect2
- PTBP2 | c.975A>C p.A325= (on ENST00000426398 / NM_001300986.2; = p.A317= on NM_021190.4) | Silent (SNP) | VAF 58/207 reads (28%) | called by muse, mutect2, varscan2
- PTCHD4 | c.1092G>A p.V364= | Silent (SNP) | VAF 115/428 reads (27%) | catalogued as rs534073402, COSV59784945, COSV59795134; called by muse, mutect2, varscan2
- QSER1 | c.2304T>G p.L768= (on ENST00000399302; = p.L897= on NM_001076786.3) | Silent (SNP) | VAF 135/302 reads (45%) | called by muse, mutect2, varscan2
- RAPGEF4 | c.2370C>T p.C790= | Silent (SNP) | VAF 57/169 reads (34%) | catalogued as rs749328932, COSV99910359; called by muse, mutect2, varscan2
- RIMS1 | c.211A>C p.R71= | Silent (SNP) | VAF 156/848 reads (18%) | catalogued as rs980106766, COSV53441304, COSV53444045, COSV53451865; called by muse, mutect2, varscan2
- RPRD2 | c.3723G>A p.S1241= | Silent (SNP) | VAF 74/261 reads (28%) | catalogued as rs374095080; called by muse, mutect2, varscan2
- SCD | c.813C>T p.F271= | Silent (SNP) | VAF 129/277 reads (47%) | catalogued as rs758975192, COSV64853330; called by muse, mutect2, varscan2
- SLC8A1 | c.2466T>G p.A822= | Silent (SNP) | VAF 186/310 reads (60%) | called by muse, mutect2, varscan2
- SMG6 | c.2238G>A p.A746= | Silent (SNP) | VAF 141/261 reads (54%) | catalogued as rs147760228, COSV53966407; called by muse, mutect2, varscan2
- SMO | c.198G>A p.R66= | Silent (SNP) | VAF 151/272 reads (56%) | called by muse, mutect2, varscan2
- SORCS1 | c.21C>T p.G7= | Silent (SNP) | VAF 11/42 reads (26%) | called by muse, mutect2, varscan2
- SRRT | c.234G>A p.K78= | Silent (SNP) | VAF 96/150 reads (64%) | called by muse, mutect2, varscan2
- SSTR1 | c.465C>T p.R155= | Silent (SNP) | VAF 56/614 reads (9%) | called by muse, mutect2
- ST8SIA2 | c.1053G>A p.E351= | Silent (SNP) | VAF 115/385 reads (30%) | called by muse, mutect2, varscan2
- SUGCT | c.156C>A p.V52= | Silent (SNP) | VAF 74/334 reads (22%) | called by muse, mutect2, varscan2
- TMTC1 | c.1179G>A p.P393= (on ENST00000539277 / NM_001193451.2; = p.P285= on NM_175861.3) | Silent (SNP) | VAF 219/347 reads (63%) | catalogued as rs372059579; called by muse, mutect2, varscan2
- TNC | c.1119C>T p.S373= | Silent (SNP) | VAF 269/353 reads (76%) | catalogued as rs746230579, COSV60784001; called by muse, mutect2, varscan2
- TP53BP2 | c.885G>A p.E295= (on ENST00000343537 / NM_001031685.3; = p.E166= on NM_005426.2) | Silent (SNP) | VAF 97/208 reads (47%) | called by muse, mutect2, varscan2
- TUBA1A | c.882T>C p.A294= | Silent (SNP) | VAF 36/788 reads (5%) | called by muse, mutect2
- TWIST1 | c.567C>T p.V189= | Silent (SNP) | VAF 100/474 reads (21%) | called by muse, mutect2, varscan2
- USP6 | c.4173G>A p.T1391= | Silent (SNP) | VAF 118/223 reads (53%) | catalogued as rs572738539, COSV51496315; called by muse, mutect2, varscan2
- ZMIZ2 | c.1395G>A p.L465= | Silent (SNP) | VAF 121/575 reads (21%) | called by muse, mutect2, varscan2
- ZNF229 | c.1800C>T p.Y600= | Silent (SNP) | VAF 85/288 reads (30%) | catalogued as rs536903685, COSV52161480; called by muse, mutect2, varscan2
- ZNF536 | c.1963C>A p.R655= | Silent (SNP) | VAF 81/229 reads (35%) | catalogued as rs770369068, COSV62819659, COSV62832846; called by muse, mutect2, varscan2
- ABCA1 | c.720+2581C>G | Intron (SNP) | VAF 68/297 reads (23%) | called by muse, mutect2, varscan2
- ABCA13 | c.12070+162G>A | Intron (SNP) | VAF 49/132 reads (37%) | called by muse, mutect2, varscan2
- AC079612.1 | n.190A>T | RNA (SNP) | VAF 289/465 reads (62%) | called by muse, mutect2, varscan2
- AC099654.5 | n.43G>A | RNA (SNP) | VAF 15/134 reads (11%) | called by muse, mutect2, varscan2
- AC114741.1 | n.229G>T | RNA (SNP) | VAF 49/145 reads (34%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65499107 G>T | 5'Flank (SNP) | VAF 30/116 reads (26%) | called by muse, mutect2, varscan2
- AP4B1 | c.1199-27G>A | Intron (SNP) | VAF 208/452 reads (46%) | catalogued as rs751648698; called by muse, mutect2, varscan2
- ARMCX4 | c.1039-4412A>T | Intron (SNP) | VAF 150/298 reads (50%) | called by muse, mutect2, varscan2
- ATP2A3 | c.219+20C>G | Intron (SNP) | VAF 46/340 reads (14%) | called by muse, mutect2, varscan2
- BID | chr22:17774443 A>C | 5'Flank (SNP) | VAF 57/241 reads (24%) | called by muse, mutect2, varscan2
- C6orf118 | c.*1C>T | 3'UTR (SNP) | VAF 40/95 reads (42%) | catalogued as rs780395167, COSV100024772; called by muse, mutect2, varscan2
- CPNE9 | c.-70G>A | 5'UTR (SNP) | VAF 106/221 reads (48%) | called by muse, varscan2
- DCHS2 | n.1141A>C | RNA (SNP) | VAF 132/411 reads (32%) | called by muse, mutect2, varscan2
- EML2 | chr19:45642429 G>C | 5'Flank (SNP) | VAF 30/101 reads (30%) | called by mutect2, varscan2
- FMN1 | c.2044-2679A>G | Intron (SNP) | VAF 115/403 reads (29%) | called by muse, mutect2, varscan2
- FOXP2 | c.258+3627A>C | Intron (SNP) | VAF 40/176 reads (23%) | called by muse, mutect2, varscan2
- G6PC3 | c.*198C>A | 3'UTR (SNP) | VAF 247/434 reads (57%) | called by muse, mutect2, varscan2
- HLA-F | chr6:29726976 G>A | 3'Flank (SNP) | VAF 253/521 reads (49%) | catalogued as rs372820182, COSV99466511; called by muse, mutect2, varscan2
- HMGB1P1 | n.70C>T | RNA (SNP) | VAF 104/722 reads (14%) | catalogued as rs758693908; called by muse, varscan2
- MEF2D | c.396+153G>A | Intron (SNP) | VAF 17/59 reads (29%) | catalogued as rs201718068; called by muse, mutect2, varscan2
- MUCL1 | c.-15C>T | 5'UTR (SNP) | VAF 30/232 reads (13%) | catalogued as rs755779012; called by muse, mutect2, varscan2
- OR51A4 | chr11:4943843 C>A | 3'Flank (SNP) | VAF 12/32 reads (38%) | called by mutect2, varscan2
- PLSCR1 | c.-9G>A | 5'UTR (SNP) | VAF 3/15 reads (20%) | called by muse, mutect2
- PLXNA4 | c.1371+4442G>T | Intron (SNP) | VAF 127/264 reads (48%) | called by muse, mutect2, varscan2
- PPFIA4 | c.-304G>C | 5'UTR (SNP) | VAF 246/247 reads (100%) | called by muse, mutect2, varscan2
- PPP2R2B | c.-59A>T | 5'UTR (SNP) | VAF 14/296 reads (5%) | catalogued as COSV60768468; called by muse, mutect2
- PTPRN | c.115+257C>T | Intron (SNP) | VAF 111/398 reads (28%) | catalogued as rs772928537; called by muse, mutect2, varscan2
- RAX | c.290-44G>A | Intron (SNP) | VAF 85/86 reads (99%) | called by muse, mutect2, varscan2
- RIMS2 | c.2083+28C>T | Intron (SNP) | VAF 50/93 reads (54%) | catalogued as rs199887006, COSV51689827; called by muse, mutect2, varscan2
- SPATA31C1 | n.523-153A>G | Intron (SNP) | VAF 287/398 reads (72%) | called by muse, mutect2, varscan2
- THBD | c.-39C>T | 5'UTR (SNP) | VAF 106/292 reads (36%) | called by muse, mutect2, varscan2
- VGLL3 | c.937+5638C>T | Intron (SNP) | VAF 24/42 reads (57%) | catalogued as rs975294831; called by muse, varscan2
- ZNF132 | c.-60T>A | 5'UTR (SNP) | VAF 89/288 reads (31%) | called by muse, mutect2, varscan2
